Somatic mutation profile of tumor specimen TCGA-AA-3861-01A (aliquot TCGA-AA-3861-01A-01W-0995-10) from TCGA case TCGA-AA-3861, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-AA-3861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0896680-8c09-473c-80e1-3f4411d2130f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3861-10A (Blood Derived Normal), aliquot TCGA-AA-3861-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68c0e186-2f46-4ab5-b8f9-c4e5a7a6dc73

The open-access MAF lists 123 somatic variants for this specimen: 86 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 34, Nonsense Mutation 4, RNA 2, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666del p.T1556Lfs*9 | Frame Shift Del (DEL) | VAF 46/77 reads (60%) | catalogued as rs587783031; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 79/167 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 30/130 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACLY | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286816033, COSV100709588, COSV61249811; called by muse, mutect2, varscan2
- AIPL1 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145112457, COSV100006040; called by muse, mutect2, varscan2
- ANK2 | c.10888G>A p.D3630N | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100004554; called by muse, mutect2, varscan2
- ASIC2 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV100727494; called by muse, mutect2
- BCORL1 | c.4683C>A p.S1561R | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99501154; called by muse, mutect2, varscan2
- BPIFB1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs770271360, COSV99487120, COSV99487627; called by muse, mutect2, varscan2
- CCL24 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99768894; called by muse, mutect2, varscan2
- CD40LG | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 37/642 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM962549, CS050421, CS982109, COSV101033577; called by muse, mutect2
- CDH11 | c.2332C>A p.R778S | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV51751364, COSV51762463; called by muse, mutect2, varscan2
- CDH2 | c.546G>T p.R182S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV52278822, COSV99298807; called by muse, mutect2, varscan2
- CDH23 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.486); catalogued as rs771868822, CM140347, COSV99824262; called by muse, mutect2, varscan2
- CERKL | c.1028G>A p.R343H (on ENST00000339098 / NM_001030311.2; = p.R317H on NM_201548.5) | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs150587104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs779359831, COSV100278049; called by muse, mutect2, varscan2
- COL6A6 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371005676; called by muse, mutect2, varscan2
- CPS1 | c.1830C>A p.S610R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV99244324; called by muse, mutect2, varscan2
- CRTAC1 | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV100086218; called by muse, mutect2, varscan2
- CSMD3 | c.3082A>T p.I1028F (on ENST00000297405 / NM_001363185.1; = p.I924F on NM_052900.3) | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs997792912, COSV99849971; called by muse, mutect2, varscan2
- CTNNA1 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 117/421 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs1203968888, COSV100242785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs145380076, COSV64724721; called by muse, mutect2, varscan2
- DARS2 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.448); catalogued as rs751581961, COSV99508949; called by muse, mutect2, varscan2
- DNER | c.1274C>A p.S425Y | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100520211; called by muse, mutect2, varscan2
- DOCK2 | c.5102G>A p.R1701K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1353944306; called by muse, mutect2
- DZANK1 | c.2018C>T p.P673L (on ENST00000262547 / NM_001099407.1; = p.P480L on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as rs368728828; called by muse, mutect2, varscan2
- ECT2L | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs539507764, COSV57809690; ClinVar: not provided; called by muse, mutect2, varscan2
- EPHA3 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100348419; called by muse, mutect2, varscan2
- ERBB4 | c.2600T>C p.L867P | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100728243; called by muse, mutect2, varscan2
- EYS | c.1338G>T p.W446C | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1280273701, COSV100677234; called by muse, mutect2, varscan2
- EYS | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV100677235, COSV61000199; called by muse, mutect2, varscan2
- FAM170A | c.702C>A p.C234* | Nonsense Mutation (SNP) | VAF 42/162 reads (26%) | catalogued as COSV100089394; called by muse, varscan2
- FAM81B | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as rs550788124, COSV99352680; called by muse, mutect2, varscan2
- FASTKD3 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99242168; called by muse, mutect2, varscan2
- FLG | c.1837A>T p.T613S | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.864); catalogued as COSV100912345; called by muse, mutect2, varscan2
- FMN2 | c.2336C>A p.T779K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.397); catalogued as COSV100147522; called by muse, mutect2, varscan2
- GAB2 | c.1769C>G p.P590R (on ENST00000361507 / NM_080491.3; = p.P552R on NM_012296.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100416918; called by muse, mutect2, varscan2
- GABRR2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140140640; called by muse, mutect2, varscan2
- GALNT11 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201883939, COSV57428583; called by muse, mutect2, varscan2
- GLE1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as CM151300, COSV59407176; called by muse, mutect2, varscan2
- HCRTR2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs199660644, COSV63794773; called by muse, mutect2, varscan2
- HEATR5A | c.1360A>T p.I454F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV101120643; called by muse, mutect2, varscan2
- IGSF8 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs768494086, COSV100081859; called by muse, varscan2
- ISLR2 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100679824; called by muse, mutect2, varscan2
- KCNQ5 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 41/136 reads (30%) | catalogued as rs1554213240, COSV100573305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF4B | c.2572G>T p.A858S | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101469418; called by muse, mutect2, varscan2
- KRT39 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 168/601 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV62916897; called by muse, mutect2, varscan2
- LRRC7 | c.1898G>A p.R633H (on ENST00000651989 / NM_001370785.2; = p.R600H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375559029, COSV50533887; called by muse, mutect2, varscan2
- MAGEB10 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100775429, COSV63311229; called by muse, mutect2, varscan2
- MAP2K4 | c.644C>G p.A215G | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV99065831; called by muse, mutect2, varscan2
- MGAT5 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99925206; called by muse, mutect2, varscan2
- MMP13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs767829684, COSV52823318; called by muse, mutect2, varscan2
- MMP16 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54152323, COSV99690706; called by muse, mutect2
- MYO9A | c.7285G>A p.V2429M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.244); catalogued as rs771852428, COSV100614506; called by muse, mutect2, varscan2
- NID1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs146611286; called by muse, mutect2, varscan2
- NLGN4X | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760432673, COSV52002990; called by muse, mutect2
- OR4Q3 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 73/351 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV59178273, COSV59179932; called by muse, mutect2, varscan2
- PARP2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs746484531, COSV99163082; called by muse, mutect2, varscan2
- PCDHA13 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56487736; called by muse, mutect2, varscan2
- PLXNA2 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); catalogued as rs770455227, COSV65442550; called by muse, mutect2, varscan2
- POMZP3 | c.346-1G>C p.X116_splice | Splice Site (SNP) | VAF 53/571 reads (9%) | catalogued as COSV99300706; called by muse, mutect2
- R3HDM1 | c.1704G>C p.M568I | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV99926921; called by muse, mutect2, varscan2
- RCN3 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99571488; called by muse, mutect2, varscan2
- RIMBP2 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs756172940, COSV99900218; called by muse, mutect2
- RPS6KA2 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769808652, COSV99692408; called by muse, mutect2, varscan2
- SAP130 | c.2968C>T p.R990* | Nonsense Mutation (SNP) | VAF 112/536 reads (21%) | catalogued as COSV52096139; called by muse, mutect2, varscan2
- SOS2 | c.426A>T p.L142F | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99366906; called by muse, mutect2, varscan2
- SRGAP1 | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749937035, COSV61898801; called by muse, mutect2, varscan2
- SULF2 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as rs373243624; called by muse, mutect2, varscan2
- TBCK | c.1999C>T p.R667W (on ENST00000273980 / NM_001163436.4; = p.R604W on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199827883, COSV56752880; called by muse, mutect2, varscan2
- TDRKH | c.1315T>C p.F439L | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100162739; called by muse, mutect2
- TNFSF11 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775440686, COSV53480359; called by muse, mutect2, varscan2
- TTN | c.81271G>T p.G27091C (on ENST00000591111; = p.G19667C on NM_003319.4) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV100633384; called by muse, mutect2, varscan2
- TTN | c.57545G>A p.R19182H (on ENST00000591111; = p.R11758H on NM_003319.4) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | PolyPhen benign (0); catalogued as rs758019778, COSV60176482; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs3820464, COSV100234360, COSV56347017, COSV56379080; called by muse, mutect2, varscan2
- USP6 | c.3380G>A p.G1127E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.093); catalogued as COSV51484278; called by muse, mutect2, varscan2
- VPS13D | c.10362G>T p.L3454F | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169785; called by muse, mutect2
- WDR72 | c.2647G>T p.G883* | Nonsense Mutation (SNP) | VAF 120/337 reads (36%) | catalogued as rs1428901566, COSV100855184; called by muse, mutect2, varscan2
- WWC3 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768225996, COSV66501709; called by muse, mutect2, varscan2
- XIRP2 | c.7577G>T p.S2526I (on ENST00000628543; = p.S2701I on NM_152381.6) | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99748244; called by muse, mutect2
- ZNF211 | c.1055A>G p.Q352R (on ENST00000347302 / NM_198855.4; = p.Q365R on NM_006385.5) | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV99560550; called by muse, mutect2, varscan2
- ZNF292 | c.2163dup p.V722Sfs*7 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs1380389009; called by mutect2, pindel, varscan2
- ZNF675 | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100705221; called by muse, mutect2
- ZNF71 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1165749950, COSV100045873, COSV60148398; called by muse, mutect2
- ADCK1 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 11/404 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- ABR | c.546T>A p.G182= (on ENST00000302538 / NM_021962.5; = p.G145= on NM_001092.5) | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99348738; called by muse, mutect2, varscan2
- ALK | c.1803C>T p.L601= | Silent (SNP) | VAF 94/287 reads (33%) | catalogued as rs769055778, COSV101202788; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALOXE3 | c.270C>T p.T90= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs1249451038, COSV58554592, COSV58554808; called by muse, mutect2
- AQR | c.3714C>T p.R1238= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs371817508; called by muse, mutect2, varscan2
- ARHGAP15 | c.1194C>T p.L398= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99714109; called by muse, mutect2, varscan2
- C12orf42 | c.639C>T p.A213= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs919261657, COSV59380129; called by muse, mutect2, varscan2
- CD22 | c.2379G>A p.T793= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs371559984, COSV50063577; called by muse, mutect2, varscan2
- DENND1C | c.2127G>A p.E709= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV100375457; called by muse, mutect2, varscan2
- DNAH10 | c.13497C>T p.N4499= (on ENST00000409039; = p.N4438= on NM_207437.3) | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs750482067, COSV99435965; called by muse, mutect2, varscan2
- DSG4 | c.2946G>A p.T982= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as rs1215614194, COSV100356472; called by muse, mutect2
- ERO1A | c.819A>G p.L273= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV101193691; called by muse, mutect2, varscan2
- GDF2 | c.1167C>A p.G389= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- GPC6 | c.108G>A p.A36= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100990143; called by muse, mutect2, varscan2
- GPR101 | c.141C>T p.V47= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99981712; called by muse, mutect2, varscan2
- H4C3 | c.210C>T p.A70= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs758943077, COSV100619671; called by muse, mutect2, varscan2
- HSD11B1 | c.138C>T p.I46= | Silent (SNP) | VAF 92/238 reads (39%) | catalogued as rs149277936; called by muse, mutect2, varscan2
- KMO | c.609C>T p.N203= | Silent (SNP) | VAF 110/394 reads (28%) | catalogued as rs146945171; called by muse, mutect2, varscan2
- KRTAP13-2 | c.105C>A p.V35= | Silent (SNP) | VAF 80/254 reads (31%) | catalogued as COSV101299680; called by muse, mutect2, varscan2
- KSR1 | c.1257C>T p.A419= (on ENST00000644974 / NM_001367810.1; = p.A282= on NM_014238.2) | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs936856347, COSV99261005; called by muse, mutect2, varscan2
- LRIT1 | c.1746C>T p.D582= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs147606323; called by muse, mutect2, varscan2
- MUC16 | c.19068T>A p.I6356= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as COSV101201967; called by muse, mutect2, varscan2
- MUC16 | c.9942C>A p.V3314= | Silent (SNP) | VAF 160/700 reads (23%) | catalogued as COSV101201968, COSV67495239; called by muse, mutect2, varscan2
- MYO7A | c.3594C>T p.C1198= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs782694195, CM112902, COSV101289295; called by muse, varscan2
- OR10G8 | c.195G>A p.S65= | Silent (SNP) | VAF 325/1007 reads (32%) | catalogued as rs140497683, COSV70908367, COSV70909159; called by muse, mutect2, varscan2
- PLD5 | c.1590A>T p.G530= (on ENST00000442594; = p.G468= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as COSV100143284; called by muse, mutect2, varscan2
- POLH | c.633G>A p.Q211= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100947908; called by muse, mutect2, varscan2
- RAI1 | c.3204G>A p.T1068= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs775060465, COSV99885199; called by muse, varscan2
- RCSD1 | c.846G>A p.P282= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs372583551; called by muse, mutect2, varscan2
- SIX4 | c.1800G>A p.S600= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV53670757; called by muse, mutect2
- SLC30A10 | c.837T>A p.I279= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as COSV100751610; called by muse, mutect2, varscan2
- SPAG16 | c.78C>T p.A26= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs768947980, COSV99794096; called by muse, mutect2, varscan2
- WFIKKN2 | c.1605C>T p.G535= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs146313081; called by muse, mutect2, varscan2
- YEATS2 | c.4081C>T p.L1361= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- ZNF699 | c.864T>C p.F288= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100427098; called by muse, mutect2, varscan2
- MASP1 | c.1303+5060G>T | Intron (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99962929; called by muse, mutect2
- OR52A4P | n.967G>A | RNA (SNP) | VAF 22/74 reads (30%) | catalogued as rs549064064; called by muse, mutect2, varscan2
- SSX6P | n.69G>A | RNA (SNP) | VAF 178/500 reads (36%) | catalogued as rs199511108; called by muse, mutect2, varscan2
